Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A02F, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A02F-01A (Primary Tumor).

TCGA #

Internal Sample ID

Diagnosis:

The material in I is a partial resection of small intestine with reactive lesions,

The material in II is a preparation of the rectosigmoid colon (in clinical terms attributable to the rectum or the sigmoid colon) with a poorly differentiated carcinoma in the area of the rectosigmoid junction (G3), with infiltration of blood and lymph vessels (L1, V1) and a lymph node metastasis (pN1).

Locally, the lesion was completely removed.

The distance from the mesorectal fascia was at least 1 cm.

The overall clinical findings and the topography should serve to determine whether this is a rectal carcinoma in the narrower sense of the term or a carcinoma of the sigmoid colon.

ICD-0-3

Carcinoma, NOS 8010/3

Site: sigmoid colon (pw (QCF) C18.7 pw 3/30/11

h.p.a. Discrepancy		X
Dist./Synchronous Primary noted		X

Source: NCI Genomic Data Commons file e2b58ee6-7327-4106-9c58-9f8378fbcc81 (TCGA-AA-A02F.F260851E-018C-4F5E-8CB4-7D85F391A41B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).